Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3CY, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3CY-01A (Primary Tumor).

Primary Tumor Site Discrepancy	corrected	
	lw	10/15/11

History Case
Pathology Report
of Pathology,

DOB: _____ Sex: M
Physician: _____

Received: _____ Pathologist: _____
Case type: Surgical History

Accession: _____

**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to _____, the section "SPECIMEN" may have been added. ****

DIAGNOSIS

(A) RIGHT LIMITED NECK DISSECTION, RIGHT PARATRACHEAL LYMPH NODE, SUPERIOR MEDIASTINAL DISSECTION WITH COMPLETION OF THYROIDECTOMY:
METASTATIC PAPILLARY CARCINOMA OF THYROID IN TWELVE LYMPH NODES.
Parathyroid tissue.
Thymus.
skeletal muscle with suture granulomas. No thyroid tissue identified.

100-0-3
carcinoma, papillary, thyroid
8260/3
Site: thyroid, NOS C73.9

lw
10/15/11

Entire report and diagnosis completed by:
Report released by:

GROSS DESCRIPTION

(A) RIGHT LIMITED NECK DISSECTION, COMPLETION THYROIDECTOMY, RIGHT PARATRACHEAL LYMPH NODE DISSECTION, SUPERIOR MEDIASTINAL DISSECTION - A right thyroid lobe with attached skeletal muscle. The entire specimen measure 7.0 x 3.8 x 1.4 cm. The thyroid measures 5.0 x 3.3 x 1.9 cm. It external surface is dark red and smooth. Cross sectioning reveals the parenchyma to be entirely involved by a papillary tumor. Representative sections are submitted to the tumor bank. The remainder of the thyroid is submitted in cassettes A1-A8. The skeletal muscle measures 4.8 x 3.0 x 1.5 cm. Cross sectioning reveals unremarkable, dark red muscle.

SECTION CODE: A1-A8, all tissue is submitted. AD1-AD3. representative sections of skeletal muscle and soft tissue.

CONSULTATION

SNOMED CODES

Source: NCI Genomic Data Commons file 8229dad3-5c55-4ce1-aed7-8f4021fe3182 (TCGA-EL-A3CY.13075C98-71F2-4A1D-B245-C3AB202CA0B4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).